Somatic mutation profile of tumor specimen TCGA-4G-AAZF-01A (aliquot TCGA-4G-AAZF-01A-12D-A46P-09) from TCGA case TCGA-4G-AAZF, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 74.2 years (27,109 days).
Specimen TCGA-4G-AAZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c173f8-c244-442f-b58a-dd150d7da9ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4G-AAZF-11A (Solid Tissue Normal), aliquot TCGA-4G-AAZF-11A-12D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd128b41-5611-4be3-97ab-6cd5f5dc32e1

The open-access MAF lists 46 somatic variants for this specimen: 35 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 10, In Frame Del 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs910211860, COSV56230719; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH20 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780788767, COSV53003819, COSV99406539; called by muse, mutect2, varscan2
- CEP250 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61175603; called by muse, mutect2, varscan2
- CSMD3 | c.9769T>A p.Y3257N (on ENST00000297405 / NM_001363185.1; = p.Y3088N on NM_052900.3) | Missense Mutation (SNP) | VAF 60/148 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52176145; called by muse, mutect2, varscan2
- FAM47B | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 135/306 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61452481; called by muse, mutect2, varscan2
- KBTBD12 | c.1820G>A p.R607Q | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751053641, COSV59678733; called by muse, mutect2, varscan2
- LRP1B | c.12956G>T p.R4319I | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as COSV67192480; called by muse, mutect2, varscan2
- P2RY10 | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV50685573; called by muse, mutect2
- PFKFB3 | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 8/68 reads (12%) | PolyPhen benign (0.018); catalogued as rs765641319; called by mutect2, varscan2
- PRKCB | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs563116744, COSV57805302; called by muse, mutect2, varscan2
- RAB4A | c.48C>A p.F16L | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as COSV64207744; called by muse, mutect2, varscan2
- RXYLT1 | c.1271_1272del p.E424Afs*2 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | catalogued as rs753296104; called by pindel, varscan2
- SLITRK3 | c.2743G>A p.V915M | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV53846078; called by muse, mutect2, varscan2
- SUN1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1368168618; called by muse, mutect2, varscan2
- TP53BP1 | c.3740G>A p.R1247H | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs151132652; called by muse, varscan2
- UPF1 | c.2125C>G p.L709V (on ENST00000599848 / NM_001297549.2; = p.L698V on NM_002911.4) | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99440236; called by muse, mutect2, varscan2
- ABLIM1 | c.994T>C p.W332R | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- CNNM4 | c.1994T>G p.L665R | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CTAG2 | c.442A>G p.M148V | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDX43 | c.354G>T p.K118N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, varscan2
- FGFR2 | c.330_351delinsA p.S110_T117delinsR | In Frame Del (DEL) | VAF 42/104 reads (40%) | called by pindel, varscan2*
- FOXP3 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HECW2 | c.1892G>C p.R631T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HSDL2 | c.760A>G p.I254V | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.97); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INPP5B | c.2662C>G p.L888V (on ENST00000373023; = p.L808V on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- MCOLN2 | c.1122C>A p.N374K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2
- NUDT12 | c.1111G>C p.V371L | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2
- OCA2 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- OR5W2 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- PRPF40A | c.635A>T p.K212I | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRN2 | c.1951C>T p.L651F | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- SCN2A | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TCEAL7 | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOP2A | c.3592G>C p.G1198R | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.594); called by muse, mutect2
- ZNF383 | c.883T>A p.S295T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- AQP8 | c.30T>C p.P10= | Silent (SNP) | VAF 39/98 reads (40%) | called by muse, mutect2, varscan2
- DDX49 | c.1351C>T p.L451= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs762567941; called by muse, mutect2, varscan2
- FLNC | c.4773G>T p.R1591= | Silent (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- GGNBP2 | c.751C>A p.R251= | Silent (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- NLRP14 | c.90C>T p.F30= | Silent (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- OAS3 | c.2896C>T p.L966= | Silent (SNP) | VAF 10/111 reads (9%) | catalogued as rs1306949975, COSV57447153; called by muse, mutect2
- RYR3 | c.1464C>T p.C488= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1358562517, COSV101212632; called by muse, mutect2, varscan2
- SLC16A14 | c.888C>T p.G296= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2, varscan2
- TNXB | c.7956C>T p.A2652= (on ENST00000647633; = p.A2405= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 88/155 reads (57%) | called by muse, mutect2, varscan2
- VGF | c.54C>T p.N18= | Silent (SNP) | VAF 53/68 reads (78%) | called by muse, mutect2, varscan2
- MFRP | chr11:119344669 G>A | 5'Flank (SNP) | VAF 17/35 reads (49%) | catalogued as rs140710522; ClinVar: uncertain significance; called by muse, mutect2, varscan2
